Somatic mutation profile of tumor specimen TCGA-ER-A2NG-06A (aliquot TCGA-ER-A2NG-06A-11D-A196-08) from TCGA case TCGA-ER-A2NG, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 45.1 years (16,470 days).
Specimen TCGA-ER-A2NG-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a190c24f-8dfe-4215-9ce4-0fd431262b90.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ER-A2NG-10A (Blood Derived Normal), aliquot TCGA-ER-A2NG-10A-01D-A198-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4543e612-57f9-48d9-bb25-f99e96807a1e

The open-access MAF lists 302 somatic variants for this specimen: 201 protein-altering or splice-affecting, 97 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 183, Silent 97, Nonsense Mutation 10, Splice Region 4, Frame Shift Del 2, 3'UTR 2, Intron 1, RNA 1, Splice Site 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ACTL8 | c.494C>T p.P165L | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.435); catalogued as COSV64861946; called by muse, mutect2, varscan2
- ADAM21 | c.1549A>T p.I517F | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV50813592; called by muse, mutect2, varscan2
- ADGRG4 | c.7312G>A p.E2438K | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.908); catalogued as COSV54968326; called by muse, mutect2, varscan2
- ANAPC1 | c.1673C>T p.P558L | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV61979890; called by muse, mutect2, varscan2
- ANKRD17 | c.3545C>T p.S1182F | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV58217072, COSV58228604; called by muse, mutect2, varscan2
- APOL1 | c.845A>C p.D282A | Missense Mutation (SNP) | VAF 19/115 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.044); catalogued as COSV59870008; called by muse, mutect2, varscan2
- ARHGAP29 | c.569C>T p.S190F | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.714); catalogued as COSV53110737; called by muse, mutect2, varscan2
- ARHGAP45 | c.2135C>G p.A712G | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.248); catalogued as COSV57436913; called by muse, mutect2, varscan2
- ASPG | c.1004C>T p.S335L | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.924); catalogued as rs987160415, COSV71933878; called by muse, mutect2, varscan2
- ATG9A | c.1999C>T p.R667W | Missense Mutation (SNP) | VAF 30/155 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.265); catalogued as rs545980763, COSV54701353; called by muse, mutect2, varscan2
- ATP6V0A2 | c.1588C>T p.P530S | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV57749403; called by muse, mutect2, varscan2
- ATRX | c.6997G>A p.E2333K | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.36); catalogued as COSV64874211, COSV64884667; called by muse, mutect2, varscan2
- BCORL1 | c.3469G>A p.E1157K | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54405583; called by muse, mutect2, varscan2
- BTBD16 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 17/75 reads (23%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as COSV53267425; called by muse, mutect2, varscan2
- BTN2A1 | c.1517C>G p.A506G | Missense Mutation (SNP) | VAF 9/137 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.958); catalogued as COSV57006668; called by muse, mutect2
- CACNA1B | c.3806A>C p.K1269T | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53151398; called by muse, mutect2, varscan2
- CASP7 | c.762A>C p.K254N | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.952); catalogued as COSV100615027; called by mutect2, varscan2
- CD163L1 | c.4067C>T p.S1356F | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.795); catalogued as COSV58011399; called by muse, mutect2, varscan2
- CD163L1 | c.3025C>T p.P1009S | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT tolerated (0.57); PolyPhen benign (0.021); catalogued as COSV58025683; called by muse, mutect2, varscan2
- CD22 | c.526T>G p.W176G | Missense Mutation (SNP) | VAF 71/155 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50071922; called by muse, mutect2, varscan2
- CDH15 | c.2149G>A p.D717N | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.027); catalogued as COSV99228841; called by muse, mutect2, varscan2
- CDH9 | c.379C>T p.R127C | Missense Mutation (SNP) | VAF 38/122 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs776212558, COSV50264628; called by muse, mutect2, varscan2
- CDK9 | c.178C>T p.P60S | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.903); catalogued as COSV64724274; called by muse, mutect2, varscan2
- CES5A | c.415C>T p.P139S | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.584); catalogued as rs865854672, COSV51871347; called by muse, mutect2, varscan2
- CHGA | c.250C>T p.L84F | Missense Mutation (SNP) | VAF 41/182 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.138); catalogued as COSV53664786; called by muse, mutect2, varscan2
- CHST7 | c.449A>T p.Q150L | Missense Mutation (SNP) | VAF 32/98 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52101460; called by muse, mutect2, varscan2
- CLDN16 | c.379G>C p.A127P | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV53229506; called by muse, mutect2, varscan2
- CLN3 | c.848T>G p.F283C (on ENST00000360019 / NM_001286104.2; = p.F307C on NM_000086.2) | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV61107994; called by muse, mutect2, varscan2
- CNNM1 | c.2176C>T p.L726= | Splice Region (SNP) | VAF 7/23 reads (30%) | catalogued as rs749240498, COSV63202163; called by muse, mutect2, varscan2
- CNTN6 | c.2135G>A p.G712E | Missense Mutation (SNP) | VAF 37/106 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63176583; called by muse, mutect2, varscan2
- CNTNAP5 | c.1186C>T p.R396* | Nonsense Mutation (SNP) | VAF 23/100 reads (23%) | catalogued as rs1447158750, COSV70472787; called by muse, mutect2, varscan2
- COL11A2 | c.3809G>C p.G1270A (on ENST00000341947 / NM_080680.3; = p.G1163A on NM_080679.2) | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV59503256, COSV59504061; called by muse, mutect2, varscan2
- COL12A1 | c.8206C>T p.P2736S | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59409497; called by muse, mutect2, varscan2
- COL18A1 | c.3773G>C p.G1258A (on ENST00000359759 / NM_130444.3; = p.G1023A on NM_030582.4) | Missense Mutation (SNP) | VAF 18/126 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV100645434; called by muse, mutect2, varscan2
- COL4A1 | c.1213G>A p.G405R | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65432716; called by muse, mutect2, varscan2
- COL4A5 | c.440G>A p.G147E | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as CD993253, COSV60362046; called by muse, mutect2, varscan2
- COL6A3 | c.2558C>T p.P853L | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.475); catalogued as rs1428773211, COSV55112785; called by muse, mutect2, varscan2
- CR2 | c.1264G>A p.E422K | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.173); catalogued as COSV65508528; called by muse, mutect2, varscan2
- CRYBG1 | c.5957G>A p.G1986D | Missense Mutation (SNP) | VAF 37/131 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64814928; called by muse, mutect2, varscan2
- CSAD | c.662C>T p.P221L (on ENST00000444623 / NM_001244705.2; = p.P248L on NM_015989.5) | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.993); catalogued as COSV57245204; called by muse, mutect2, varscan2
- CSMD3 | c.2821C>T p.Q941* (on ENST00000297405 / NM_001363185.1; = p.Q837* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 17/60 reads (28%) | catalogued as COSV52335085; called by muse, mutect2, varscan2
- CYP4B1 | c.410A>C p.H137P | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54726591; called by muse, mutect2, varscan2
- CYP4B1 | c.808G>A p.D270N | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.53); PolyPhen benign (0.029); catalogued as COSV54722648; called by muse, mutect2, varscan2
- CYP4Z1 | c.1255G>A p.E419K | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.5); PolyPhen benign (0.193); catalogued as COSV61966929; called by muse, mutect2, varscan2
- DCX | c.69G>A p.M23I | Missense Mutation (SNP) | VAF 36/134 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.017); catalogued as COSV57575937; called by muse, mutect2, varscan2
- DIAPH2 | c.1903G>A p.E635K | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.494); catalogued as COSV100235187, COSV100235956; called by muse, mutect2, varscan2
- DIS3L | c.568G>A p.D190N (on ENST00000319212 / NM_001143688.3; = p.D107N on NM_133375.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/105 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV59914678; called by muse, mutect2, varscan2
- DNAH7 | c.12025G>A p.E4009K | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.83); PolyPhen benign (0.271); catalogued as COSV56789359; called by muse, mutect2, varscan2
- DNAH7 | c.10807C>T p.P3603S | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV56766285; called by muse, mutect2, varscan2
- ELAVL2 | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 38/128 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.688); catalogued as COSV56357615, COSV56360085; called by muse, mutect2, varscan2
- EPHA4 | c.1082C>T p.S361F | Missense Mutation (SNP) | VAF 36/189 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.588); catalogued as COSV56029452; called by muse, mutect2, varscan2
- FAM163B | c.381C>G p.S127R | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.37); PolyPhen benign (0.079); catalogued as COSV63206650; called by muse, mutect2, varscan2
- FAM171B | c.1310C>T p.P437L | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.999); catalogued as COSV59009241; called by muse, mutect2, varscan2
- FBP2 | c.841G>A p.E281K | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64695927; called by muse, mutect2, varscan2
- FRMD7 | c.1444C>T p.P482S | Missense Mutation (SNP) | VAF 49/180 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); catalogued as COSV53745435; called by muse, mutect2, varscan2
- GABRA2 | c.400T>A p.S134T | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62920465; called by muse, mutect2, varscan2
- GAD2 | c.1637G>A p.S546N | Missense Mutation (SNP) | VAF 37/90 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV52169658; called by muse, mutect2, varscan2
- GATM | c.548C>T p.P183L | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67541274; called by muse, mutect2, varscan2
- GGA3 | c.1010G>C p.S337T (on ENST00000537686 / NM_138619.4; = p.S304T on NM_014001.5) | Missense Mutation (SNP) | VAF 45/86 reads (52%) | SIFT tolerated (0.53); PolyPhen benign (0.005); catalogued as rs768846061, COSV55459304; called by muse, mutect2, varscan2
- GIMAP8 | c.1117G>A p.D373N | Missense Mutation (SNP) | VAF 82/187 reads (44%) | SIFT tolerated (0.26); PolyPhen benign (0.069); catalogued as COSV56234533; called by muse, mutect2, varscan2
- GLB1 | c.1351C>T p.P451S | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT tolerated (0.4); PolyPhen benign (0.184); catalogued as rs267599772, COSV56568465; called by muse, mutect2, varscan2
- GPRC6A | c.2071G>A p.D691N | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.5); PolyPhen benign (0.101); catalogued as COSV59956293; called by muse, mutect2, varscan2
- GPRC6A | c.833T>G p.L278R | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV59956299; called by muse, mutect2, varscan2
- HIVEP3 | c.323G>A p.G108D | Missense Mutation (SNP) | VAF 34/172 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.051); catalogued as COSV56024744; called by muse, mutect2, varscan2
- HSD17B10 | c.430G>A p.G144R | Missense Mutation (SNP) | VAF 7/76 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as COSV51448957; called by muse, mutect2
- INTS13 | c.1192G>C p.D398H | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53902024; called by muse, mutect2, varscan2
- IQUB | c.2297G>A p.G766D | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0); catalogued as rs1479137457, COSV61243203; called by muse, mutect2, varscan2
- IRF2 | c.940T>G p.S314A | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as COSV66930816; called by muse, mutect2, varscan2
- JDP2 | c.236G>A p.R79Q | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.864); catalogued as rs747632515, COSV50868620, COSV99966783; called by muse, mutect2, varscan2
- KDM3B | c.5039C>T p.A1680V | Missense Mutation (SNP) | VAF 31/137 reads (23%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.842); catalogued as COSV58695969; called by muse, mutect2, varscan2
- KLF14 | c.592C>T p.P198S | Missense Mutation (SNP) | VAF 221/523 reads (42%) | SIFT tolerated (0.53); PolyPhen benign (0.03); catalogued as rs782777502, COSV60589140; called by muse, mutect2, varscan2
- KLHL24 | c.142C>T p.H48Y | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.831); catalogued as COSV54429095; called by muse, mutect2, varscan2
- KLHL7 | c.595C>G p.L199V (on ENST00000339077 / NM_001031710.3; = p.L151V on NM_018846.5) | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.477); catalogued as COSV59164950; called by muse, mutect2, varscan2
- KLK6 | c.52G>A p.E18K | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.017); catalogued as rs913095973, COSV100037833, COSV59564983; called by muse, mutect2, varscan2
- KRT72 | c.1180G>A p.G394S | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0.072); catalogued as COSV53377222; called by muse, mutect2, varscan2
- KRTAP10-6 | c.782G>A p.C261Y | Missense Mutation (SNP) | VAF 42/186 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); catalogued as rs1555926610, COSV59982024; called by muse, mutect2, varscan2
- LRFN2 | c.575C>T p.T192I | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.348); catalogued as COSV57835347; called by muse, mutect2, varscan2
- MAGI2 | c.3032-1G>A p.X1011_splice | Splice Site (SNP) | VAF 75/128 reads (59%) | catalogued as COSV62702331; called by muse, mutect2, varscan2
- MAN2B1 | c.1790C>T p.P597L | Missense Mutation (SNP) | VAF 34/171 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.044); catalogued as COSV55475658; called by muse, mutect2, varscan2
- MAP3K15 | c.3064G>A p.E1022K | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.424); catalogued as COSV58839883; called by muse, mutect2, varscan2
- MAP7D3 | c.176A>C p.D59A | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as COSV60172823; called by muse, varscan2
- MARCHF6 | c.481G>C p.V161L | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.17); catalogued as COSV56887706; called by muse, mutect2, varscan2
- MAST4 | c.6211G>A p.E2071K (on ENST00000403625 / NM_001164664.2; = p.E1882K on NM_015183.3) | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.197); catalogued as rs1163172379, COSV55144240; called by muse, mutect2, varscan2
- MID2 | c.2131G>A p.D711N | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.83); catalogued as COSV53314744; called by muse, mutect2, varscan2
- MKI67 | c.6252G>C p.Q2084H | Missense Mutation (SNP) | VAF 71/240 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.755); catalogued as COSV64077388; called by muse, mutect2, varscan2
- MXRA5 | c.3287C>T p.P1096L | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV54252583; called by muse, mutect2, varscan2
- MYF6 | c.10G>A p.D4N | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs748635316, COSV57353620; called by muse, mutect2, varscan2
- MYH11 | c.1527C>G p.I509M | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.666); catalogued as COSV55571345, COSV55571944; called by muse, mutect2, varscan2
- MYO1H | c.988C>T p.L330F | Missense Mutation (SNP) | VAF 23/107 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV60444883; called by muse, mutect2, varscan2
- N4BP2L1 | c.289G>C p.E97Q | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.197); catalogued as COSV58412576, COSV58414172; called by muse, mutect2, varscan2
- NCKAP5 | c.1351C>T p.P451S | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.022); catalogued as rs778049835, COSV58461656; called by muse, mutect2, varscan2
- NCOR2 | c.3959G>A p.R1320K | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as rs537038342, COSV62305399; called by muse, mutect2, varscan2
- NDNF | c.1334C>T p.P445L | Missense Mutation (SNP) | VAF 16/139 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1224119020, COSV65634749; called by muse, mutect2, varscan2
- NDNF | c.1333C>T p.P445S | Missense Mutation (SNP) | VAF 17/151 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as rs1245187391, COSV65634050; called by muse, mutect2
- NDUFS3 | c.252A>T p.L84F | Missense Mutation (SNP) | VAF 40/181 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs200420802, COSV55456536; called by muse, mutect2, varscan2
- NEU4 | c.676G>A p.A226T (on ENST00000391969 / NM_001167602.3; = p.A238T on NM_080741.4) | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV57992234; called by muse, mutect2
- NLGN1 | c.280C>T p.R94C | Missense Mutation (SNP) | VAF 47/133 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs374685079; called by muse, mutect2, varscan2
- NONO | c.431C>T p.A144V | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.721); catalogued as COSV52140673; called by muse, mutect2, varscan2
- NPHS1 | c.3554C>T p.P1185L | Missense Mutation (SNP) | VAF 32/204 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.031); catalogued as rs555255264, COSV100800437, COSV62287222; called by muse, mutect2, varscan2
- NUFIP1 | c.1398A>C p.E466D | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV64792346; called by muse, mutect2
- NWD1 | c.2791G>A p.D931N | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV60352860; called by muse, mutect2, varscan2
- OBSCN | c.5884C>G p.L1962V | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.589); catalogued as COSV52836248, COSV99476031; called by muse, mutect2, varscan2
- OPRD1 | c.751G>A p.E251K | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.101); catalogued as COSV52384031; called by mutect2, varscan2
- OR1L1 | c.673C>T p.H225Y (on ENST00000373686; = p.H175Y on NM_001005236.3) | Missense Mutation (SNP) | VAF 55/237 reads (23%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.952); catalogued as rs756003274, COSV58936885; called by muse, mutect2, varscan2
- OR2C1 | c.146C>T p.S49F | Missense Mutation (SNP) | VAF 32/180 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.048); catalogued as COSV59240770; called by muse, mutect2, varscan2
- OR2J2 | c.73G>A p.E25K | Missense Mutation (SNP) | VAF 29/153 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs868815525, COSV65847786; called by muse, mutect2, varscan2
- OR52J3 | c.532C>A p.H178N | Missense Mutation (SNP) | VAF 26/99 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66747874; called by muse, mutect2, varscan2
- OR5AR1 | c.4G>A p.D2N | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV57254332; called by muse, mutect2, varscan2
- OR6C4 | c.355G>A p.D119N | Missense Mutation (SNP) | VAF 33/128 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV101263163, COSV67793185; called by muse, mutect2, varscan2
- OR8B2 | c.856C>T p.P286S | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV66664714; called by muse, mutect2, varscan2
- ORC1 | c.961C>T p.R321* | Nonsense Mutation (SNP) | VAF 17/134 reads (13%) | catalogued as rs367611068; called by muse, mutect2, varscan2
- PAGE2 | c.77C>T p.S26F | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.771); catalogued as COSV66596253; called by muse, mutect2
- PBRM1 | c.3548G>A p.W1183* (on ENST00000296302 / NM_001366071.2; = p.W1158* on NM_018313.5) | Nonsense Mutation (SNP) | VAF 16/36 reads (44%) | catalogued as COSV56261440; called by muse, mutect2, varscan2
- PBX4 | c.547G>A p.G183S | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.023); catalogued as rs748607444, COSV52064911; called by muse, mutect2, varscan2
- PCARE | c.1687G>A p.D563N | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.775); catalogued as COSV59058582; called by muse, mutect2, varscan2
- PCDH9 | c.2903C>T p.P968L | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100123345; called by muse, mutect2, varscan2
- PCDH9 | c.2902C>T p.P968S | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60555788; called by muse, mutect2, varscan2
- PCDHB1 | c.731G>A p.R244Q | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs376346263; called by muse, mutect2, varscan2
- PCDHB15 | c.1615C>T p.P539S | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.956); catalogued as COSV51005245, COSV51426642; called by muse, mutect2, varscan2
- PCNT | c.2858A>T p.H953L | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.203); catalogued as COSV64033558; called by muse, mutect2, varscan2
- PCSK2 | c.971C>T p.S324F | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.516); catalogued as COSV52744477; called by muse, mutect2, varscan2
- PEX5 | c.1809C>G p.I603M (on ENST00000420616; = p.I595M on NM_000319.5) | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV56958848; called by muse, mutect2, varscan2
- PGK2 | c.778G>A p.E260K | Missense Mutation (SNP) | VAF 23/107 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.029); catalogued as COSV59162902; called by muse, mutect2, varscan2
- PI16 | c.532C>T p.Q178* | Nonsense Mutation (SNP) | VAF 13/99 reads (13%) | catalogued as COSV101028819; called by muse, mutect2, varscan2
- PIK3C2B | c.3539C>T p.S1180F | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV65814555; called by muse, mutect2, varscan2
- PKHD1L1 | c.10201G>A p.D3401N | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.18); catalogued as COSV65749295; called by muse, mutect2
- PLCB4 | c.3175G>A p.E1059K | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.61); PolyPhen benign (0.036); catalogued as COSV53820352; called by muse, mutect2
- PLEC | c.7183G>C p.D2395H (on ENST00000322810 / NM_201380.4; = p.D2285H on NM_000445.5) | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.972); catalogued as COSV59701559; called by muse, mutect2, varscan2
- PPIG | c.334A>G p.M112V | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1262829463, COSV53646587; called by muse, mutect2, varscan2
- PPIP5K1 | c.281T>G p.I94S | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100613510; called by mutect2, varscan2
- PREX1 | c.2614A>G p.K872E | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as COSV64257397; called by muse, mutect2, varscan2
- PRKG1 | c.1176C>T p.V392= | Splice Region (SNP) | VAF 5/22 reads (23%) | catalogued as COSV100907489, COSV64778960; called by muse, mutect2, varscan2
- PROS1 | c.854T>A p.V285D | Missense Mutation (SNP) | VAF 11/128 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as COSV67777532; called by muse, mutect2
- PRX | c.2894C>T p.S965L | Missense Mutation (SNP) | VAF 70/168 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.778); catalogued as rs1328567193, COSV52533931; called by muse, mutect2, varscan2
- PSG8 | c.1253T>G p.I418S | Missense Mutation (SNP) | VAF 63/462 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV100126592; called by muse, mutect2, varscan2
- PTGER2 | c.47G>C p.R16P | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV55420327; called by muse, mutect2, varscan2
- PZP | c.2681T>C p.V894A | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs923908769, COSV54371476; called by muse, mutect2, varscan2
- RADIL | c.884C>G p.P295R | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV68203963; called by muse, mutect2
- RARA | c.641C>T p.S214L | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.406); catalogued as COSV54197704; called by muse, mutect2, varscan2
- RAVER2 | c.991C>T p.Q331* | Nonsense Mutation (SNP) | VAF 9/36 reads (25%) | catalogued as COSV104397639, COSV53811413; called by muse, mutect2, varscan2
- RCOR3 | c.838C>T p.P280S | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.01); catalogued as COSV65367030; called by muse, mutect2
- REG1B | c.94C>T p.P32S | Missense Mutation (SNP) | VAF 42/156 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV59307992; called by muse, mutect2, varscan2
- RFX6 | c.1597C>T p.L533F | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.845); catalogued as rs1352888505, COSV60584348, COSV60589160; called by muse, mutect2, varscan2
- RGS7 | c.581G>A p.R194K | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV58562737; called by muse, mutect2, varscan2
- RLIM | c.740C>T p.S247L | Missense Mutation (SNP) | VAF 13/120 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV60329385; called by muse, mutect2, varscan2
- RYR1 | c.6273C>T p.P2091= | Splice Region (SNP) | VAF 4/26 reads (15%) | catalogued as rs1295561951, COSV62112481; called by muse, mutect2
- SAGE1 | c.368G>A p.R123Q | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT tolerated (0.88); PolyPhen benign (0.005); catalogued as rs781929129, COSV61012521; called by muse, mutect2, varscan2
- SARDH | c.843G>A p.M281I | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.291); catalogued as COSV53836186; called by muse, mutect2, varscan2
- SFTPB | c.328C>T p.P110S | Missense Mutation (SNP) | VAF 31/161 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.066); catalogued as COSV60892698; called by muse, mutect2, varscan2
- SHQ1 | c.755A>T p.Q252L | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV57768679; called by muse, mutect2, varscan2
- SIGLEC7 | c.516G>A p.W172* | Nonsense Mutation (SNP) | VAF 47/164 reads (29%) | catalogued as rs767198744, COSV58318110; called by muse, mutect2, varscan2
- SLC22A10 | c.629C>T p.S210F | Missense Mutation (SNP) | VAF 32/87 reads (37%) | SIFT tolerated (0.21); PolyPhen benign (0.033); catalogued as COSV60423791; called by muse, mutect2, varscan2
- SLC24A4 | c.589C>T p.R197C | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.013); catalogued as rs183808799; called by muse, mutect2, varscan2
- SLC4A10 | c.2817T>G p.Y939* (on ENST00000446997 / NM_001354461.2; = p.Y909* on NM_022058.4 and 5 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 8/44 reads (18%) | catalogued as COSV55802098; called by muse, mutect2, varscan2
- SLC4A8 | c.2685G>A p.M895I | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.053); catalogued as COSV60658724; called by muse, mutect2, varscan2
- SLC6A11 | c.1084G>A p.E362K | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.643); catalogued as rs141411603, COSV54393676, COSV54399734; called by muse, mutect2, varscan2
- SLC6A13 | c.782G>A p.G261E | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58257369; called by muse, mutect2, varscan2
- SLCO1B3 | c.1581T>A p.D527E | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.033); catalogued as COSV53947501; called by muse, mutect2, varscan2
- SLCO2A1 | c.325G>C p.A109P | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60490044; called by muse, mutect2, varscan2
- SMARCC1 | c.2317C>G p.L773V | Missense Mutation (SNP) | VAF 39/107 reads (36%) | SIFT tolerated (0.28); PolyPhen benign (0.039); catalogued as COSV54387318; called by muse, mutect2, varscan2
- SPO11 | c.745G>A p.G249R | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61995851; called by muse, mutect2, varscan2
- STAG3 | c.2282C>G p.S761C | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.068); catalogued as COSV57935593; called by muse, mutect2, varscan2
- STAU2 | c.-18G>C | Splice Region (SNP) | VAF 8/43 reads (19%) | catalogued as COSV62480189; called by muse, mutect2, varscan2
- STON1 | c.532G>A p.E178K | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (0.33); PolyPhen benign (0.031); catalogued as COSV59139158; called by muse, mutect2, varscan2
- SYNE1 | c.13208C>T p.S4403L (on ENST00000367255 / NM_182961.4; = p.S4332L on NM_033071.3) | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.023); catalogued as rs139490297; called by muse, mutect2, varscan2
- TACC2 | c.4361G>A p.G1454E | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.019); catalogued as COSV57775274; called by muse, mutect2, varscan2
- TAL2 | c.214G>A p.G72R | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV61884130; called by muse, mutect2, varscan2
- TBXT | c.296A>G p.N99S | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT tolerated (0.72); PolyPhen benign (0.005); catalogued as COSV51620358; called by muse, mutect2, varscan2
- TCEAL3 | c.335G>C p.R112T | Missense Mutation (SNP) | VAF 16/124 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as COSV54581568; called by muse, varscan2
- TFAP2D | c.1291G>A p.E431K | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV50428167, COSV50449750; called by muse, mutect2, varscan2
- TLR2 | c.1054C>T p.P352S | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV52608435; called by muse, mutect2, varscan2
- TM2D3 | c.69G>C p.Q23H | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.823); catalogued as COSV100255016; called by muse, mutect2, varscan2
- TM6SF2 | c.301G>A p.E101K | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.185); catalogued as rs1395291293, COSV66985511, COSV66985977; called by muse, mutect2, varscan2
- TMED4 | c.486G>C p.Q162H | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.771); catalogued as rs375279841; called by muse, mutect2, varscan2
- TMEM156 | c.604G>A p.E202K | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.943); catalogued as COSV60745838; called by muse, mutect2, varscan2
- TNFRSF8 | c.1249C>T p.R417W | Missense Mutation (SNP) | VAF 44/144 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs140319459; called by muse, mutect2, varscan2
- TRIM55 | c.1343G>A p.G448D | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.212); catalogued as rs754934747, COSV52551418; called by muse, mutect2, varscan2
- TSPAN12 | c.127C>G p.L43V | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.682); catalogued as COSV56082213; called by muse, mutect2, varscan2
- TTC3 | c.4738G>C p.V1580L | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.65); PolyPhen benign (0.001); catalogued as COSV61296882; called by muse, mutect2, varscan2
- TXNL1 | c.247C>T p.R83* | Nonsense Mutation (SNP) | VAF 38/150 reads (25%) | catalogued as rs965035395, COSV54178870; called by muse, mutect2, varscan2
- USP54 | c.2099C>T p.S700F | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as COSV60448618; called by muse, mutect2, varscan2
- VASH2 | c.664T>G p.F222V (on ENST00000517399 / NM_001301056.2; = p.F178V on NM_024749.5) | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.178); catalogued as COSV55119731; called by muse, mutect2, varscan2
- VCAN | c.8662G>C p.E2888Q | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.154); catalogued as COSV54095771; called by muse, mutect2, varscan2
- VWC2 | c.772G>A p.E258K | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.324); catalogued as COSV61487545; called by muse, mutect2, varscan2
- WDR88 | c.179C>T p.P60L | Missense Mutation (SNP) | VAF 27/195 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.706); catalogued as COSV50129287; called by muse, mutect2, varscan2
- XIRP2 | c.3562A>C p.N1188H (on ENST00000628543; = p.N1363H on NM_152381.6) | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.042); catalogued as rs757767610, COSV54737794; called by muse, mutect2, varscan2
- YLPM1 | c.5860G>C p.E1954Q | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.895); catalogued as COSV53119812; called by muse, mutect2
- ZBED9 | c.2560G>A p.E854K | Missense Mutation (SNP) | VAF 34/128 reads (27%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.973); catalogued as COSV71729809; called by muse, mutect2, varscan2
- ZGRF1 | c.1096C>A p.L366I | Missense Mutation (SNP) | VAF 7/76 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0.077); catalogued as COSV52203489; called by muse, mutect2
- ZNF169 | c.1111G>A p.E371K | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV61766813; called by muse, mutect2
- ZNF366 | c.958C>T p.Q320* | Nonsense Mutation (SNP) | VAF 7/35 reads (20%) | catalogued as rs750775921, COSV59219448; called by muse, mutect2, varscan2
- ZNF395 | c.1441G>A p.G481R | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.33); catalogued as rs762209668, COSV60428585, COSV60430567; called by muse, mutect2, varscan2
- ZNF407 | c.1471G>A p.V491M | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.31); catalogued as COSV55272146; called by muse, mutect2, varscan2
- ZNF608 | c.2681C>T p.P894L | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60441832; called by muse, mutect2, varscan2
- ZNF638 | c.3751A>T p.I1251F | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52497968; called by muse, mutect2, varscan2
- ZNF878 | c.716C>T p.P239L | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.893); catalogued as rs747991787, COSV72156133; called by muse, varscan2
- C19orf44 | c.1567del p.V523* | Frame Shift Del (DEL) | VAF 15/88 reads (17%) | called by mutect2, pindel, varscan2
- CASZ1 | c.896_899delinsTTG p.S299Ifs*8 | Frame Shift Del (DEL) | VAF 19/169 reads (11%) | called by pindel, varscan2*
- SPATA31A1 | c.2951G>A p.G984E | Missense Mutation (SNP) | VAF 63/266 reads (24%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.762); called by muse, mutect2, varscan2
- TBC1D3B | c.460A>T p.R154W | Missense Mutation (SNP) | VAF 50/161 reads (31%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.987); called by mutect2, varscan2
- AC098582.1 | c.1365C>T p.I455= | Silent (SNP) | VAF 16/47 reads (34%) | catalogued as COSV52025571; called by muse, mutect2, varscan2
- ACAN | c.6519C>T p.T2173= | Silent (SNP) | VAF 23/105 reads (22%) | catalogued as COSV61370506; called by muse, mutect2, varscan2
- ADGRA1 | c.624C>T p.L208= | Silent (SNP) | VAF 5/13 reads (38%) | catalogued as rs758893904, COSV74142966; called by muse, mutect2, varscan2
- ADGRF3 | c.2772G>A p.G924= (on ENST00000311519 / NM_001145168.1; = p.G725= on NM_153835.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 9/30 reads (30%) | catalogued as COSV61053681; called by muse, mutect2, varscan2
- AFF2 | c.3678G>A p.G1226= | Silent (SNP) | VAF 20/140 reads (14%) | catalogued as COSV54009542; called by muse, mutect2, varscan2
- ALG2 | c.571C>T p.L191= | Silent (SNP) | VAF 24/86 reads (28%) | catalogued as COSV53061011; called by muse, mutect2, varscan2
- ALS2 | c.4458C>T p.Y1486= | Silent (SNP) | VAF 13/47 reads (28%) | catalogued as COSV51893487; called by muse, mutect2, varscan2
- ANK1 | c.5325G>A p.R1775= | Silent (SNP) | VAF 15/80 reads (19%) | catalogued as COSV55881860, COSV55897567; called by muse, mutect2, varscan2
- ARHGEF10 | c.402C>T p.P134= (on ENST00000398564; = p.P110= on NM_014629.4) | Silent (SNP) | VAF 19/106 reads (18%) | catalogued as rs151043667, COSV50683338; called by muse, mutect2, varscan2
- BMP3 | c.1293G>A p.G431= | Silent (SNP) | VAF 35/137 reads (26%) | catalogued as COSV51088693; called by muse, mutect2, varscan2
- CACNA1H | c.4326C>T p.I1442= | Silent (SNP) | VAF 36/152 reads (24%) | catalogued as rs1171391522, COSV61986074; called by muse, mutect2, varscan2
- CAMKK2 | c.375C>T p.S125= | Silent (SNP) | VAF 70/258 reads (27%) | catalogued as rs146945076; called by muse, mutect2, varscan2
- CATSPER1 | c.1986C>T p.F662= | Silent (SNP) | VAF 10/41 reads (24%) | catalogued as rs1467357733, COSV56413850; called by muse, mutect2, varscan2
- CCDC6 | c.918G>A p.R306= | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as rs1187599946, COSV99569826; called by muse, mutect2, varscan2
- CECR2 | c.348C>T p.I116= | Silent (SNP) | VAF 52/125 reads (42%) | catalogued as COSV52849211; called by muse, mutect2, varscan2
- CLCNKA | c.441G>A p.K147= | Silent (SNP) | VAF 69/268 reads (26%) | catalogued as rs377275023; called by muse, mutect2, varscan2
- COL12A1 | c.588G>A p.Q196= | Silent (SNP) | VAF 13/77 reads (17%) | catalogued as rs748928908, COSV59396361; called by muse, mutect2, varscan2
- COL18A1 | c.3774A>C p.G1258= (on ENST00000359759 / NM_130444.3; = p.G1023= on NM_030582.4) | Silent (SNP) | VAF 18/129 reads (14%) | catalogued as rs529768077, COSV100645435, COSV60586649; called by muse, mutect2, varscan2
- COL6A2 | c.1962C>T p.S654= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as rs150253422; ClinVar: likely benign / uncertain significance; called by mutect2, varscan2
- COL6A2 | c.2781C>G p.A927= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as COSV52430489; called by muse, mutect2
- CORO7 | c.1290C>T p.S430= | Silent (SNP) | VAF 4/15 reads (27%) | catalogued as COSV52034529; called by muse, mutect2, varscan2
- CRY2 | c.1086C>T p.I362= | Silent (SNP) | VAF 22/121 reads (18%) | catalogued as COSV69889312; called by muse, mutect2, varscan2
- CYP2B6 | c.1089C>T p.L363= | Silent (SNP) | VAF 14/85 reads (16%) | catalogued as COSV57845733; called by muse, mutect2, varscan2
- DBH | c.1278G>A p.R426= | Silent (SNP) | VAF 14/32 reads (44%) | catalogued as rs747612165, COSV101257171; called by muse, mutect2
- DSCAM | c.1083G>A p.R361= | Silent (SNP) | VAF 37/315 reads (12%) | catalogued as COSV68037553; called by muse, mutect2, varscan2
- ENC1 | c.1254C>T p.D418= | Silent (SNP) | VAF 44/149 reads (30%) | catalogued as COSV56631543; called by muse, mutect2, varscan2
- FAM13B | c.21T>G p.P7= | Silent (SNP) | VAF 19/66 reads (29%) | catalogued as COSV50375756; called by muse, mutect2, varscan2
- FAM181A | c.708G>A p.L236= | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as COSV50891971; called by muse, mutect2, varscan2
- FRYL | c.7752A>C p.I2584= | Silent (SNP) | VAF 15/66 reads (23%) | catalogued as COSV51963885; called by muse, mutect2, varscan2
- GPX6 | c.34C>T p.L12= | Silent (SNP) | VAF 8/60 reads (13%) | catalogued as COSV62659258; called by muse, mutect2
- HK2 | c.2670C>T p.F890= | Silent (SNP) | VAF 48/204 reads (24%) | catalogued as COSV51875650; called by muse, mutect2, varscan2
- IGHG3 | c.912C>G p.P304= | Silent (SNP) | VAF 59/270 reads (22%) | called by muse, mutect2, varscan2
- IGLV5-48 | c.165C>T p.Y55= | Silent (SNP) | VAF 51/194 reads (26%) | catalogued as rs767273891; called by muse, varscan2
- IGSF8 | c.1428C>T p.A476= | Silent (SNP) | VAF 9/30 reads (30%) | catalogued as rs753199239, COSV58759332; called by muse, mutect2, varscan2
- IL18RAP | c.1068A>G p.R356= | Silent (SNP) | VAF 9/69 reads (13%) | catalogued as COSV51829649; called by muse, mutect2, varscan2
- IL1RAPL1 | c.1581G>A p.L527= | Silent (SNP) | VAF 12/49 reads (24%) | catalogued as COSV56305310; called by muse, mutect2, varscan2
- ILDR2 | c.465G>A p.G155= | Silent (SNP) | VAF 22/67 reads (33%) | catalogued as COSV54828152; called by muse, mutect2, varscan2
- ITFG1 | c.1203C>T p.F401= | Silent (SNP) | VAF 16/75 reads (21%) | catalogued as COSV57750390, COSV57757000; called by muse, mutect2, varscan2
- KCND1 | c.1218C>T p.V406= | Silent (SNP) | VAF 22/53 reads (42%) | catalogued as COSV54416294; called by muse, mutect2, varscan2
- KDM5C | c.3792C>T p.A1264= | Silent (SNP) | VAF 10/24 reads (42%) | catalogued as COSV64770589; called by muse, mutect2, varscan2
- KLK6 | c.51G>A p.E17= | Silent (SNP) | VAF 15/50 reads (30%) | catalogued as COSV100037707, COSV100037834; called by muse, mutect2, varscan2
- KRT24 | c.1422G>A p.R474= | Silent (SNP) | VAF 88/206 reads (43%) | catalogued as rs866964813, COSV52882204; called by muse, mutect2, varscan2
- LRRC6 | c.147C>G p.L49= | Silent (SNP) | VAF 9/44 reads (20%) | catalogued as rs768257025, COSV51546553, COSV51548124; called by muse, mutect2, varscan2
- MAGEA11 | c.28C>T p.L10= | Silent (SNP) | VAF 9/84 reads (11%) | catalogued as COSV60758284, COSV60758982; called by muse, mutect2, varscan2
- MAGEC2 | c.540G>A p.V180= | Silent (SNP) | VAF 60/216 reads (28%) | catalogued as rs759290309, COSV56001122; called by muse, mutect2, varscan2
- MAGEL2 | c.2808C>T p.H936= | Silent (SNP) | VAF 9/84 reads (11%) | catalogued as COSV58569389; called by muse, mutect2
- MAPK4 | c.723C>T p.I241= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as rs372444429; called by muse, mutect2
- MAPRE1 | c.522G>A p.K174= | Silent (SNP) | VAF 80/309 reads (26%) | catalogued as COSV65033659; called by muse, mutect2, varscan2
- MN1 | c.3906G>A p.R1302= | Silent (SNP) | VAF 30/103 reads (29%) | catalogued as rs561643116, COSV56562745; called by muse, mutect2, varscan2
- MYF5 | c.69C>T p.S23= | Silent (SNP) | VAF 9/46 reads (20%) | catalogued as COSV57355182; called by muse, mutect2, varscan2
- MYO1H | c.987C>T p.V329= | Silent (SNP) | VAF 24/109 reads (22%) | catalogued as COSV60452106; called by muse, mutect2, varscan2
- NDUFA9 | c.21C>T p.S7= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as rs745611828, COSV56932478; called by muse, mutect2
- NUP62CL | c.420C>T p.I140= | Silent (SNP) | VAF 16/117 reads (14%) | catalogued as COSV65236667, COSV65237188; called by muse, mutect2, varscan2
- OR10G3 | c.876G>A p.R292= | Silent (SNP) | VAF 19/80 reads (24%) | catalogued as COSV57811308; called by muse, mutect2, varscan2
- OR10G8 | c.246T>G p.T82= | Silent (SNP) | VAF 29/105 reads (28%) | catalogued as COSV70908274, COSV70908825; called by muse, mutect2, varscan2
- OR13C4 | c.684G>A p.T228= | Silent (SNP) | VAF 30/130 reads (23%) | catalogued as rs141274906, COSV52925666; called by muse, mutect2, varscan2
- OR4C16 | c.849G>A p.V283= | Silent (SNP) | VAF 5/13 reads (38%) | catalogued as COSV58940773; called by muse, mutect2, varscan2
- OR4D11 | c.111G>A p.T37= | Silent (SNP) | VAF 37/152 reads (24%) | catalogued as rs146036577, COSV57587347; called by muse, mutect2, varscan2
- PCDHA2 | c.132C>T p.F44= | Silent (SNP) | VAF 21/93 reads (23%) | catalogued as COSV65371599; called by muse, mutect2, varscan2
- PCDHB4 | c.741G>T p.G247= | Silent (SNP) | VAF 24/112 reads (21%) | catalogued as rs782261386, COSV52027599; called by muse, mutect2, varscan2
- PCLO | c.555C>T p.S185= | Silent (SNP) | VAF 25/48 reads (52%) | catalogued as COSV61671575; called by muse, mutect2, varscan2
- PI16 | c.531C>T p.Y177= | Silent (SNP) | VAF 13/101 reads (13%) | catalogued as COSV101028816; called by muse, mutect2, varscan2
- PLAC8 | c.225G>A p.R75= | Silent (SNP) | VAF 24/92 reads (26%) | catalogued as COSV61048373; called by muse, mutect2, varscan2
- PLB1 | c.3909C>T p.S1303= | Silent (SNP) | VAF 14/75 reads (19%) | catalogued as COSV59836800; called by muse, mutect2, varscan2
- POTEE | c.2806C>T p.L936= | Silent (SNP) | VAF 20/278 reads (7%) | catalogued as COSV58246301; called by muse, mutect2
- POTEF | c.2913C>T p.S971= | Silent (SNP) | VAF 4/14 reads (29%) | called by mutect2, varscan2
- PSG8 | c.1254C>T p.I418= | Silent (SNP) | VAF 64/462 reads (14%) | catalogued as COSV60613138; called by muse, mutect2, varscan2
- PXDNL | c.2634G>A p.V878= | Silent (SNP) | VAF 11/47 reads (23%) | catalogued as COSV62499685; called by muse, mutect2, varscan2
- RALYL | c.156C>T p.S52= | Silent (SNP) | VAF 13/46 reads (28%) | catalogued as rs534853015, COSV72826155; called by muse, mutect2, varscan2
- RERE | c.4119C>T p.P1373= | Silent (SNP) | VAF 5/27 reads (19%) | catalogued as COSV61950676; called by muse, mutect2, varscan2
- SAMSN1 | c.942A>G p.E314= | Silent (SNP) | VAF 12/35 reads (34%) | catalogued as COSV53478280; called by muse, mutect2, varscan2
- SAMSN1 | c.12A>G p.R4= | Silent (SNP) | VAF 30/83 reads (36%) | catalogued as COSV53478296; called by muse, mutect2, varscan2
- SCAMP5 | c.429G>A p.T143= | Silent (SNP) | VAF 71/262 reads (27%) | catalogued as rs778160445, COSV62642807; called by muse, mutect2, varscan2
- SCN3A | c.720G>A p.L240= | Silent (SNP) | VAF 29/107 reads (27%) | catalogued as COSV51826152, COSV99328257; called by muse, mutect2, varscan2
- SCRIB | c.1962T>G p.A654= | Silent (SNP) | VAF 17/57 reads (30%) | catalogued as COSV57594059; called by muse, mutect2, varscan2
- SEC14L5 | c.1287C>T p.P429= | Silent (SNP) | VAF 15/50 reads (30%) | catalogued as rs373532254; called by muse, mutect2, varscan2
- SEC16B | c.834T>G p.P278= | Silent (SNP) | VAF 11/46 reads (24%) | catalogued as COSV57630548; called by muse, mutect2, varscan2
- SEMA3E | c.105G>C p.L35= | Silent (SNP) | VAF 7/44 reads (16%) | catalogued as COSV57110893; called by muse, mutect2, varscan2
- SERPINA4 | c.150G>A p.K50= | Silent (SNP) | VAF 29/121 reads (24%) | catalogued as COSV54071843; called by muse, mutect2, varscan2
- SF3B1 | c.2316C>T p.I772= | Silent (SNP) | VAF 9/73 reads (12%) | catalogued as COSV59229060; called by muse, mutect2, varscan2
- SF3B3 | c.2934C>T p.L978= | Silent (SNP) | VAF 16/70 reads (23%) | catalogued as COSV56791732; called by muse, mutect2, varscan2
- SFTPB | c.528C>T p.L176= | Silent (SNP) | VAF 15/70 reads (21%) | catalogued as rs147209702, COSV100667098; called by muse, mutect2, varscan2
- SLC22A2 | c.72C>T p.F24= | Silent (SNP) | VAF 6/61 reads (10%) | catalogued as COSV65267440; called by muse, mutect2, varscan2
- SLC35B4 | c.729C>T p.L243= | Silent (SNP) | VAF 21/38 reads (55%) | catalogued as COSV65985583; called by muse, mutect2, varscan2
- SLC5A8 | c.1608G>A p.G536= | Silent (SNP) | VAF 36/213 reads (17%) | catalogued as COSV73311261; called by muse, mutect2, varscan2
- SPG7 | c.1176C>T p.A392= (on ENST00000268704; = p.A399= on NM_003119.4) | Silent (SNP) | VAF 17/77 reads (22%) | catalogued as rs373627269; ClinVar: likely benign; called by muse, mutect2, varscan2
- TADA2A | c.807C>T p.F269= | Silent (SNP) | VAF 20/72 reads (28%) | called by muse, mutect2, varscan2
- TAPBP | c.996C>T p.L332= | Silent (SNP) | VAF 14/54 reads (26%) | catalogued as COSV70457849; called by muse, mutect2, varscan2
- TET1 | c.6105C>T p.H2035= | Silent (SNP) | VAF 26/78 reads (33%) | catalogued as COSV65390016; called by muse, mutect2, varscan2
- TLE4 | c.1392T>C p.F464= | Silent (SNP) | VAF 21/94 reads (22%) | catalogued as COSV54642346; called by muse, mutect2, varscan2
- TNFSF14 | c.606C>T p.F202= | Silent (SNP) | VAF 38/62 reads (61%) | catalogued as COSV55591201; called by muse, mutect2, varscan2
- TRAV6 | c.126G>A p.K42= | Silent (SNP) | VAF 11/36 reads (31%) | called by muse, mutect2, varscan2
- TTN | c.55770G>A p.L18590= (on ENST00000591111; = p.L11166= on NM_003319.4) | Silent (SNP) | VAF 53/208 reads (25%) | catalogued as COSV60383370; called by muse, mutect2, varscan2
- WARS2 | c.228C>T p.L76= | Silent (SNP) | VAF 17/96 reads (18%) | catalogued as COSV52483077, COSV99345909; called by muse, mutect2, varscan2
- ZFC3H1 | c.3579A>T p.T1193= | Silent (SNP) | VAF 14/54 reads (26%) | catalogued as COSV66436288; called by muse, mutect2, varscan2
- ZNF283 | c.1458C>T p.S486= | Silent (SNP) | VAF 24/177 reads (14%) | catalogued as rs1228657407, COSV61033268; called by muse, mutect2, varscan2
- ZNF462 | c.2694C>T p.F898= | Silent (SNP) | VAF 25/85 reads (29%) | catalogued as rs750192528, COSV52951965; called by muse, mutect2, varscan2
- FBXL21P | n.618T>G | RNA (SNP) | VAF 36/161 reads (22%) | catalogued as COSV51810376; called by muse, mutect2, varscan2
- PDE4D | c.455+124708A>T | Intron (SNP) | VAF 51/200 reads (26%) | catalogued as COSV100508973; called by muse, mutect2, varscan2
- PITHD1 | c.*1G>A | 3'UTR (SNP) | VAF 16/84 reads (19%) | catalogued as COSV99862232; called by muse, mutect2, varscan2
- PITHD1 | c.*2G>A | 3'UTR (SNP) | VAF 15/85 reads (18%) | catalogued as COSV99862237; called by muse, mutect2, varscan2
